Somatic mutation profile of tumor specimen C3N-01502-01 (aliquot CPT0065570009) from CPTAC case C3N-01502, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.4 years (27,522 days).
Specimen C3N-01502-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03755ae1-4a54-495a-91fe-842bcfcabd90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01502-31 (Blood Derived Normal), aliquot CPT0070700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35812ec9-4415-4d09-974f-5ba9af5832e5

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Nonsense Mutation 4, Intron 2, 3'UTR 1, 5'Flank 1, In Frame Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 33/426 reads (8%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2
- APOBEC1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.664); catalogued as rs1340514921; called by muse, mutect2
- BAAT | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 22/310 reads (7%) | catalogued as COSV52287479; called by muse, mutect2
- BAD | c.438C>G p.S146R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs894529854; called by muse, mutect2
- EXOC1 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 8/241 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100637853; called by muse, mutect2
- FAM124A | c.380C>A p.P127H (on ENST00000322475 / NM_001242312.2; = p.P163H on NM_145019.4) | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696426; called by muse, mutect2
- HIVEP3 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs762816658; called by muse, mutect2
- IGLV3-1 | c.179A>T p.Q60L | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs375625744; called by muse, mutect2
- KRT83 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 32/602 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs751797447, COSV53339250; called by muse, mutect2
- LRPPRC | c.3005A>T p.E1002V | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99581352; called by muse, mutect2
- MEGF9 | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV100879404; called by muse, mutect2
- MKI67 | c.6117C>G p.I2039M | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs1323049349; called by muse, mutect2
- PCDHA11 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 40/866 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as rs782716769; called by muse, mutect2
- PCDHGA8 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53898242; called by muse, mutect2
- SHROOM4 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363295605; called by muse, mutect2
- TAP1 | c.278G>A p.W93* | Nonsense Mutation (SNP) | VAF 13/208 reads (6%) | catalogued as rs950606129, COSV100841138; called by muse, mutect2
- ABCB6 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- AC004922.1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2
- ADGRA2 | c.3570C>G p.H1190Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.205); called by muse, mutect2
- ADGRE1 | c.47A>T p.H16L | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2
- ALS2 | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.842); called by muse, mutect2
- BRCC3 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPRS | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- DCLRE1C | c.855C>G p.I285M (on ENST00000378278 / NM_001350965.2; = p.I170M on NM_022487.4) | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.713); called by muse, mutect2
- FAM133A | c.398A>T p.K133I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- FAM200B | c.728T>G p.V243G | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- FGF20 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- FLACC1 | c.906C>A p.D302E | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, mutect2
- GLI3 | c.873A>T p.K291N | Missense Mutation (SNP) | VAF 26/536 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GLYATL3 | c.742A>T p.N248Y | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); called by muse, mutect2
- MID1IP1 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- NABP1 | c.266A>C p.Y89S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2
- NLRP8 | c.2415G>C p.W805C | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.013); called by muse, mutect2
- NUTM1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- OTOG | c.7829G>T p.C2610F | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCED1B | c.1101_1118del p.F368_F373del | In Frame Del (DEL) | VAF 17/244 reads (7%) | called by mutect2, pindel
- PRORP | c.545T>A p.L182* | Nonsense Mutation (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- RIMBP2 | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 19/470 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); called by muse, mutect2
- SACS | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SLC15A1 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 9/257 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); called by muse, mutect2
- SYT3 | c.1402+2T>G p.X468_splice | Splice Site (SNP) | VAF 15/286 reads (5%) | called by muse, mutect2
- TEPSIN | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- TESK2 | c.1057C>G p.H353D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- TNS4 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.107); called by muse, mutect2
- C10orf71 | c.3975G>A p.P1325= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as rs936455982, COSV60506306; called by muse, mutect2
- EXOC3L1 | c.1332G>T p.L444= | Silent (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- INSYN2B | c.324A>G p.P108= | Silent (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- MYO1F | c.447G>C p.P149= | Silent (SNP) | VAF 28/558 reads (5%) | called by muse, mutect2
- NRIP1 | c.2103T>C p.S701= | Silent (SNP) | VAF 11/191 reads (6%) | catalogued as rs1441849670; called by muse, mutect2
- OR6Y1 | c.330G>C p.V110= | Silent (SNP) | VAF 24/435 reads (6%) | called by muse, mutect2
- PEX5L | c.195A>T p.S65= | Silent (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- POU2F1 | c.1677C>T p.T559= (on ENST00000541643 / NM_001365848.1; = p.T582= on NM_002697.4) | Silent (SNP) | VAF 40/334 reads (12%) | catalogued as rs745888834; called by muse, mutect2, varscan2
- SELENOT | c.318T>C p.P106= | Silent (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- ZNF37A | c.1335A>G p.G445= | Silent (SNP) | VAF 10/214 reads (5%) | catalogued as rs1436769794; called by muse, mutect2
- CACNA1B | c.5223-1560C>T | Intron (SNP) | VAF 22/254 reads (9%) | catalogued as rs770886030, COSV53117835; called by muse, mutect2
- CCDC83 | chr11:85853094 C>G | 5'Flank (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- COPS3 | c.762+363A>C | Intron (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- ITIH5 | c.*3220del | 3'UTR (DEL) | VAF 12/95 reads (13%) | catalogued as rs111905334; called by mutect2, varscan2
- VPS29 | c.-12C>G | 5'UTR (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
